Somatic mutation profile of tumor specimen 0DIDSG from CCDI case PBBVFG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.1 years (4,795 days).
Specimen 0DIDSG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d96c0fc-e755-4373-a1a3-babb5eed5f22.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIDS0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c35f66e6-e06c-430c-a660-06be2c8a0ff1

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 3, Nonsense Mutation 1, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KLHL35 | c.1531T>G p.W511G | Missense Mutation (SNP) | VAF 113/491 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66219592; called by muse, mutect2, varscan2
- MBD5 | c.3463G>A p.D1155N | Missense Mutation (SNP) | VAF 27/551 reads (5%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.112); catalogued as COSV68698568; called by muse, mutect2
- PAX6 | c.50A>G p.N17S | Missense Mutation (SNP) | VAF 46/249 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as CM981463; called by muse, mutect2, varscan2
- RASGRF2 | c.3277G>A p.V1093M | Missense Mutation (SNP) | VAF 49/804 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.246); catalogued as rs202044259; called by muse, mutect2
- SACS | c.10115C>A p.S3372* | Nonsense Mutation (SNP) | VAF 156/520 reads (30%) | catalogued as COSV66540283; called by mutect2, varscan2
- SF3B3 | c.823C>T p.R275W | Missense Mutation (SNP) | VAF 100/213 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1291727994; called by muse, mutect2, varscan2
- TPO | c.1127C>T p.A376V | Missense Mutation (SNP) | VAF 32/540 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.061); catalogued as rs1377963820; called by muse, mutect2
- ADAMTS10 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 24/693 reads (3%) | SIFT tolerated (1); PolyPhen possibly damaging (0.876); called by muse, mutect2
- COPB2 | c.1546G>T p.V516F | Missense Mutation (SNP) | VAF 22/386 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.03); called by muse, mutect2
- CYP4A11 | c.841G>C p.E281Q | Missense Mutation (SNP) | VAF 30/640 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.314); called by muse, mutect2
- DAPK1 | c.4207C>G p.L1403V | Missense Mutation (SNP) | VAF 23/343 reads (7%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2
- MKRN2 | c.236A>T p.H79L | Missense Mutation (SNP) | VAF 117/429 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- NRXN2 | c.4678C>A p.L1560M | Missense Mutation (SNP) | VAF 13/419 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.762); called by muse, mutect2
- PDGFRA | c.2471T>A p.V824D | Missense Mutation (SNP) | VAF 23/769 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RGMB | c.1217A>G p.H406R (on ENST00000513185 / NM_001366508.1; = p.H447R on NM_001012761.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 156/510 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- FRY | c.3888T>A p.A1296= | Silent (SNP) | VAF 18/565 reads (3%) | called by muse, mutect2
- GRIA4 | c.411G>A p.S137= | Silent (SNP) | VAF 207/666 reads (31%) | catalogued as rs745523574; called by muse, mutect2, varscan2
- NLRP12 | c.1929C>T p.S643= | Silent (SNP) | VAF 11/347 reads (3%) | called by muse, mutect2
- KRI1 | c.168+56C>G | Intron (SNP) | VAF 79/199 reads (40%) | catalogued as rs1489791490; called by muse, mutect2, varscan2
- TEX33 | chr22:36991123 C>G | 3'Flank (SNP) | VAF 26/170 reads (15%) | catalogued as rs571883798; called by muse, mutect2
